Somatic mutation profile of tumor specimen TCGA-CV-A6K1-01A (aliquot TCGA-CV-A6K1-01A-11D-A31L-08) from TCGA case TCGA-CV-A6K1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 65.3 years (23,848 days).
Specimen TCGA-CV-A6K1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57b1b54a-4a92-4eef-b139-13a3f8b3ffed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6K1-10A (Blood Derived Normal), aliquot TCGA-CV-A6K1-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3020d793-037c-4522-9597-28f3ce1a58e4

The open-access MAF lists 572 somatic variants for this specimen: 431 protein-altering or splice-affecting, 120 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 311, Silent 120, Frame Shift Del 73, Nonsense Mutation 18, Frame Shift Ins 17, Splice Site 8, Intron 7, RNA 7, 5'UTR 4, Splice Region 2, In Frame Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868417981, COSV100477191; ClinVar: likely pathogenic; called by muse, mutect2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 5/17 reads (29%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 26/43 reads (60%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- TRMT1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542184779, COSV99679013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14574T>A p.S4858R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291402; called by muse, mutect2, varscan2
- ABCA7 | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs1241826513, COSV99566445; called by muse, mutect2, varscan2
- ABCC10 | c.931G>T p.G311C (on ENST00000372530 / NM_001198934.2; = p.G268C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99767762; called by muse, mutect2, varscan2
- ABHD11 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99766901; called by muse, mutect2
- AC136428.1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768485072, COSV101434983; called by muse, mutect2, varscan2
- ACOT8 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV99467767; called by muse, mutect2, varscan2
- ACTN4 | c.1817C>T p.S606L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs747590691, COSV99400610; called by muse, mutect2, varscan2
- ADAMTS12 | c.2542A>G p.T848A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100711507; called by muse, mutect2, varscan2
- ADAMTS16 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942314; called by muse, mutect2, varscan2
- ADAMTS8 | c.945C>G p.I315M | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1464266609, COSV99961384; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as rs1207827568, COSV65888827; called by muse, mutect2, varscan2
- ADCY1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52033824; called by muse, mutect2, varscan2
- ADGRB2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1416404805, COSV57073850; called by muse, mutect2, varscan2
- ADGRL1 | c.937C>T p.R313C (on ENST00000340736 / NM_001008701.3; = p.R308C on NM_014921.5) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243120331, COSV61564696; called by muse, mutect2, varscan2
- AGBL1 | c.3240C>A p.F1080L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV101223997; called by muse, mutect2, varscan2
- AGPAT2 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100452035, COSV58247124; called by muse, mutect2, varscan2
- AK9 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV100394130; called by muse, mutect2, varscan2
- ALG5 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99523532, COSV99523778; called by muse, mutect2, varscan2
- ALPL | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100876300, COSV66375972; called by muse, mutect2, varscan2
- ANKS1B | c.2566G>A p.G856R (on ENST00000547776 / NM_152788.4; = p.G82R on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228597; called by muse, mutect2, varscan2
- ANLN | c.2685G>C p.K895N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99732684; called by muse, mutect2, varscan2
- ANO5 | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100202078; called by muse, mutect2, varscan2
- ANXA4 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV101268833; called by muse, varscan2
- AP4B1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528147130, COSV56725492; called by muse, mutect2, varscan2
- AP4M1 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.327); catalogued as COSV100385100; called by muse, mutect2, varscan2
- APC | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs149154604, COSV57322722, COSV99969383; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP29 | c.2108A>G p.Q703R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99558714; called by muse, mutect2, varscan2
- ASH1L | c.5948G>A p.R1983H | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs766422974, COSV64213107; called by muse, mutect2, varscan2
- ASPM | c.8923C>A p.L2975I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); catalogued as COSV99660892; called by muse, varscan2
- ATP13A3 | c.3341del p.L1114Yfs*22 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV55469110; called by mutect2, pindel
- ATP8B4 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as COSV99466861; called by muse, mutect2, varscan2
- B3GNT6 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100845802; called by muse, mutect2, varscan2
- B4GALT7 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV50352592; called by muse, mutect2, varscan2
- BAG1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV56303865; called by muse, mutect2, varscan2
- BICRA | c.2810dup p.P938Tfs*127 | Frame Shift Ins (INS) | VAF 20/37 reads (54%) | catalogued as rs755506199; called by mutect2, varscan2
- BIRC6 | c.5041G>A p.V1681M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV101428589; called by muse, mutect2, varscan2
- BRCA2 | c.9692C>T p.S3231L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101200912, COSV66337532; called by muse, mutect2, varscan2
- BRIP1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV51999787; called by muse, mutect2, varscan2
- BTN2A2 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100760550; called by muse, mutect2, varscan2
- C19orf12 | c.147G>T p.M49I (on ENST00000392278 / NM_001031726.3; = p.M38I on NM_031448.6) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100080627; called by muse, mutect2, varscan2
- C7orf57 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV100817212; called by muse, mutect2, varscan2
- CACNA1E | c.6095C>T p.S2032L (on ENST00000367573 / NM_001205293.3; = p.S1989L on NM_000721.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs1049589906, COSV62395266; called by muse, mutect2, varscan2
- CARD6 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99621118; called by muse, mutect2, varscan2
- CASQ1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs557844880, COSV100927347; called by muse, mutect2, varscan2
- CBFA2T2 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100656485; called by muse, mutect2, varscan2
- CBFA2T2 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100656489; called by muse, mutect2, varscan2
- CBLC | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV54321153, COSV54323355, COSV99542236; called by muse, mutect2, varscan2
- CCDC7 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs954423198, COSV99511810; called by muse, mutect2, varscan2
- CCM2L | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99395389; called by muse, mutect2, varscan2
- CCT6A | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99303663; called by muse, mutect2, varscan2
- CD4 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.899); catalogued as COSV99163861; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH11 | c.1894G>T p.V632F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV51771673; called by muse, mutect2, varscan2
- CDH4 | c.2676C>A p.D892E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV100849397; called by muse, mutect2, varscan2
- CDO1 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99164819; called by muse, mutect2, varscan2
- CEP104 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100986701; called by muse, mutect2, varscan2
- CEP131 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs754285910, COSV99488818; called by muse, mutect2, varscan2
- CEP192 | c.4156G>C p.V1386L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV100381840; called by muse, mutect2, varscan2
- CFAP46 | c.7214del p.P2405Lfs*5 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs1344439240; called by mutect2, pindel
- CFAP53 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs764418705, COSV101275018; called by muse, mutect2, varscan2
- CFAP65 | c.4040del p.N1347Ifs*63 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs1553521569; called by mutect2, pindel, varscan2
- CHD4 | c.3980G>A p.R1327H (on ENST00000357008 / NM_001363606.2; = p.R1340H on NM_001273.5) | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898406; called by muse, mutect2, varscan2
- CHMP6 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs374101426; called by muse, mutect2, varscan2
- CHST6 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100178549; called by muse, mutect2, varscan2
- CILP | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56024708, COSV99973792; called by muse, mutect2, varscan2
- CLEC17A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs755048797, COSV60428857, COSV60430726; called by muse, mutect2
- CLIP3 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV100859350; called by muse, varscan2
- COL16A1 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.712); catalogued as COSV99595157; called by muse, mutect2, varscan2
- COL22A1 | c.4558C>A p.P1520T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759469460, COSV57330861, COSV57346033; called by muse, mutect2, varscan2
- COL22A1 | c.4016G>A p.G1339D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100279934; called by muse, mutect2, varscan2
- COL22A1 | c.3655G>T p.G1219W | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279935; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 14/43 reads (33%) | catalogued as rs760493024; called by mutect2, varscan2
- COL6A6 | c.4626del p.T1544Hfs*49 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs746783819, COSV62016775; called by mutect2, pindel, varscan2
- CP | c.2962G>T p.G988C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM066552, COSV99224357; called by muse, mutect2, varscan2
- CPNE6 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1232661142, COSV99393640; called by muse, mutect2, varscan2
- CSMD3 | c.9073C>T p.R3025C (on ENST00000297405 / NM_001363185.1; = p.R2856C on NM_052900.3) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775065918, COSV52095077; called by muse, mutect2, varscan2
- CTSW | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748607117, COSV57173006; called by muse, mutect2, varscan2
- CYC1 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100010545; called by muse, mutect2, varscan2
- CYP8B1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100296248; called by muse, mutect2, varscan2
- DAAM2 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1338159414, COSV99226413; called by muse, mutect2, varscan2
- DCAF12L2 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.955); catalogued as rs752148756, COSV100758602, COSV100758766; called by muse, mutect2, varscan2
- DCP1B | c.548del p.K183Rfs*2 | Frame Shift Del (DEL) | VAF 39/146 reads (27%) | catalogued as rs1191848585; called by mutect2, pindel, varscan2
- DCX | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100576685; called by muse, mutect2, varscan2
- DENND4B | c.1729C>G p.L577V | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.664); catalogued as COSV100768841; called by muse, mutect2, varscan2
- DGKE | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV99401138; called by muse, mutect2, varscan2
- DIAPH3 | c.1832C>A p.P611H (on ENST00000400324 / NM_001042517.2; = p.P348H on NM_030932.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV57382798, COSV99934113; called by muse, mutect2, varscan2
- DISP3 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609634; called by muse, mutect2, varscan2
- DLG1 | c.1703G>T p.S568I | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100015795; called by muse, mutect2, varscan2
- DLGAP3 | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99333047; called by muse, mutect2, varscan2
- DNAJA3 | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99276916; called by muse, mutect2, varscan2
- DNAJC18 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100122185; called by muse, varscan2
- DNM1 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV100360221; called by muse, mutect2, varscan2
- DNM2 | c.1631T>C p.V544A (on ENST00000355667 / NM_001005360.3; = p.V540A on NM_004945.3) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100117758; called by muse, mutect2, varscan2
- DOCK1 | c.135G>C p.W45C | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99731802; called by muse, mutect2, varscan2
- DYNC2H1 | c.5000T>C p.L1667P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517068; called by muse, mutect2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs369293935; called by mutect2, varscan2
- EGLN2 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100393813; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4A3 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53922635; called by muse, mutect2, varscan2
- ERCC6 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163269726, COSV63391020; called by muse, mutect2, varscan2
- ERMP1 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99284712; called by muse, mutect2, varscan2
- ETS1 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100091190; called by muse, mutect2, varscan2
- EXTL2 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1458437820, COSV100921121; called by muse, mutect2, varscan2
- F12 | c.1753A>G p.S585G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99499870; called by muse, mutect2, varscan2
- F13A1 | c.1201del p.Q401Rfs*64 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs1290008988, CM960522; called by mutect2, pindel, varscan2
- FAM135A | c.923C>T p.A308V (on ENST00000370479 / NM_001351599.1; = p.A291V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776272559, COSV99526461; called by muse, mutect2, varscan2
- FAM184A | c.3414C>A p.F1138L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100138179; called by muse, mutect2, varscan2
- FAM71A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202026670, COSV99674804; called by muse, mutect2, varscan2
- FAM91A1 | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100593730; called by muse, mutect2, varscan2
- FANCI | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV100168405; called by muse, varscan2
- FANCI | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs368711186; called by muse, varscan2
- FASN | c.4126G>A p.A1376T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs374469081; called by muse, mutect2
- FAT1 | c.4361C>G p.P1454R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499563; called by muse, mutect2, varscan2
- FAT1 | c.1768A>T p.T590S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV101499564; called by muse, mutect2, varscan2
- FCGRT | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV99571410; called by muse, mutect2, varscan2
- FGFR2 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100336959; called by muse, mutect2, varscan2
- FKBP15 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99439491; called by muse, mutect2, varscan2
- FLG2 | c.4109A>T p.H1370L | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101166086; called by muse, mutect2
- FMO1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772867301, COSV100707987, COSV61446650; called by muse, mutect2, varscan2
- FMO5 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV99567316; called by muse, mutect2, varscan2
- FNDC1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1289859555, COSV51937887; called by mutect2, varscan2
- FOXF1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1369235355, COSV99296667; called by muse, mutect2, varscan2
- FSHB | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.875); catalogued as COSV99569508; called by muse, mutect2, varscan2
- GAK | c.208-2A>T p.X70_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100033957; called by muse, mutect2, varscan2
- GAS2 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99535504; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs78929040; called by mutect2, pindel, varscan2
- GLTPD2 | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100165335, COSV58702498; called by muse, mutect2, varscan2
- GNAT3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs779508773, COSV101242414; called by muse, mutect2, varscan2
- GPR31 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100834166; called by muse, mutect2, varscan2
- GRIK2 | c.2157A>C p.K719N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100028281; called by muse, mutect2, varscan2
- GRK2 | c.2014G>A p.V672M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.27); catalogued as rs61763970, COSV57752104; called by muse, mutect2, varscan2
- GRM5 | c.3559T>C p.S1187P (on ENST00000305447 / NM_001143831.2; = p.S1155P on NM_000842.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100553626; called by muse, mutect2, varscan2
- GRM5 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs748341324, COSV100553630; called by muse, mutect2, varscan2
- GRM8 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279655; called by muse, mutect2, varscan2
- GSKIP | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV101347626; called by muse, mutect2
- GUCY2D | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs545271894, COSV99643691, COSV99644207; called by muse, mutect2, varscan2
- H2AC20 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs1553759933, COSV58611674, COSV58612207; called by muse, varscan2
- HBG1 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100400686; called by muse, varscan2
- HCFC1 | c.5567T>C p.L1856P | Missense Mutation (SNP) | VAF 141/223 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129654; called by muse, mutect2, varscan2
- HDAC4 | c.3182C>T p.S1061L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as rs781413370, COSV100614015; called by muse, mutect2, varscan2
- HDAC4 | c.2399del p.P800Lfs*30 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs748900140; called by mutect2, pindel, varscan2
- HEATR5B | c.3671A>G p.D1224G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99249995; called by muse, mutect2, varscan2
- HEPH | c.3132G>A p.M1044I (on ENST00000343002; = p.M777I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100295437; called by muse, mutect2, varscan2
- HINFP | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747537186, COSV100640875; called by muse, mutect2, varscan2
- HIPK2 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs758831488, COSV100702459; called by muse, mutect2, varscan2
- HLA-B | c.619+1G>A p.X207_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV69522901; called by muse, varscan2
- HLA-G | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64407196; called by muse, mutect2, varscan2
- HLA-G | c.896-1G>T p.X299_splice | Splice Site (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100827161; called by muse, mutect2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 54/164 reads (33%) | catalogued as rs760021495; called by mutect2, varscan2
- IL18RAP | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99962274; called by muse, mutect2, varscan2
- INPP5B | c.1096T>G p.W366G (on ENST00000373023; = p.W286G on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886562; called by muse, mutect2
- IPO13 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100961313; called by muse, mutect2, varscan2
- IRF2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1561084975, COSV101165876; called by muse, mutect2, varscan2
- ITGAM | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 57/155 reads (37%) | catalogued as COSV54945091; called by muse, mutect2, varscan2
- JAK2 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV101077834; called by muse, mutect2, varscan2
- JMJD1C | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV101232455; called by muse, mutect2, varscan2
- KANSL1L | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55991521, COSV99910847; called by muse, mutect2, varscan2
- KATNA1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100167942; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KCTD8 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV63589179; called by muse, mutect2, varscan2
- KIAA1549L | c.3839A>G p.K1280R (on ENST00000321505; = p.K1577R on NM_012194.3) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV99684154; called by muse, mutect2, varscan2
- KIF26B | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832949; called by muse, mutect2, varscan2
- KIRREL3 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV101585819; called by muse, mutect2, varscan2
- KLF11 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100007858; called by muse, mutect2, varscan2
- KRTAP12-2 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100554963; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99441563; called by muse, mutect2, varscan2
- LIN7C | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1275696603, COSV53414612; called by muse, mutect2, varscan2
- LONRF2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66542703; called by muse, mutect2, varscan2
- LPAR4 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 50/76 reads (66%) | catalogued as COSV101425151; called by muse, mutect2, varscan2
- LRIT3 | c.1337A>G p.Q446R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1178175489, COSV100016339; called by muse, mutect2, varscan2
- LRP1B | c.11245G>T p.D3749Y | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV101259275; called by muse, mutect2, varscan2
- LRPPRC | c.3901-2A>G p.X1301_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99581232; called by muse, mutect2, varscan2
- LRRC14 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs148279627; called by muse, mutect2, varscan2
- LRRC40 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs746389314, COSV100918804; called by muse, mutect2, varscan2
- LRRK1 | c.5435C>T p.S1812F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99442189; called by muse, mutect2, varscan2
- LRRK2 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100110903; called by muse, mutect2, varscan2
- LRRTM3 | c.4+2T>C p.X2_splice | Splice Site (SNP) | VAF 63/206 reads (31%) | catalogued as COSV100791843; called by muse, mutect2, varscan2
- LSAMP | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762856060, COSV100372271; called by muse, mutect2, varscan2
- MAB21L1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV100082915; called by muse, mutect2, varscan2
- MACC1 | c.2501T>C p.L834P | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs768655721, COSV100256133; called by muse, mutect2, varscan2
- MACC1 | c.1232del p.N411Tfs*23 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs761473889, COSV60540689; called by mutect2, pindel, varscan2
- MACO1 | c.1819A>G p.I607V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV100975273; called by muse, mutect2, varscan2
- MAGED2 | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV54499496; called by muse, mutect2, varscan2
- MAML1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs200741540, COSV52990202; called by muse, mutect2, varscan2
- MAST2 | c.3961G>T p.G1321C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100788635; called by muse, mutect2, varscan2
- MATN2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV54719010; called by muse, varscan2
- MDM1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 30/54 reads (56%) | catalogued as COSV100292022; called by muse, mutect2, varscan2
- MEGF8 | c.2002G>T p.V668F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs749703192, COSV52099385, COSV99238356; called by muse, mutect2, varscan2
- MGME1 | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); catalogued as COSV100891368; called by muse, varscan2
- MICAL1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 129/449 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100668693; called by muse, mutect2, varscan2
- MLXIPL | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100515483; called by muse, mutect2, varscan2
- MMP20 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV99497884; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2415A>C p.Q805H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100825197; called by muse, mutect2, varscan2
- MPLKIP | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.774); catalogued as COSV100003757; called by muse, mutect2
- MPV17 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99274487; called by muse, mutect2, varscan2
- MROH9 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100882938; called by muse, mutect2, varscan2
- MS4A15 | c.523G>A p.V175M (on ENST00000405633 / NM_001098835.2; = p.V82M on NM_152717.3) | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs200402929, COSV100558918; called by muse, mutect2, varscan2
- MTUS1 | c.2958_2961del p.T987Cfs*53 (on ENST00000262102 / NM_001363061.1; = p.T153Cfs*53 on NM_020749.4) | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs764227364; called by mutect2, pindel, varscan2
- MX2 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100416099; called by muse, mutect2, varscan2
- MYCBPAP | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100088781; called by muse, mutect2
- MYH1 | c.174del p.K59Rfs*2 | Frame Shift Del (DEL) | VAF 70/236 reads (30%) | catalogued as rs1177807589; called by mutect2, pindel, varscan2
- MYH7B | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 112/331 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99483167; called by muse, mutect2, varscan2
- MYH8 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101238611; called by muse, mutect2, varscan2
- MYL9 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99641133; called by muse, mutect2, varscan2
- MYOC | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231657; called by muse, mutect2, varscan2
- MYPOP | c.1139dup p.H381Tfs*69 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | catalogued as rs757587344; called by mutect2, varscan2
- MZF1 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.891); catalogued as rs763744696, COSV99285397; called by muse, varscan2
- NAV2 | c.970C>A p.P324T (on ENST00000396087 / NM_001244963.2; = p.P301T on NM_145117.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100586800; called by muse, mutect2, varscan2
- NCAPD3 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1398377255, COSV73258353; called by muse, mutect2, varscan2
- NDUFS2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs773333372, COSV63487342; called by muse, mutect2, varscan2
- NECTIN2 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754949827, COSV99374977; called by muse, mutect2, varscan2
- NECTIN3 | c.1416dup p.E473Rfs*12 | Frame Shift Ins (INS) | VAF 15/33 reads (45%) | catalogued as rs760367541; called by mutect2, varscan2
- NIBAN1 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836526, COSV62286515; called by muse, mutect2, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as COSV52567752; called by mutect2, pindel, varscan2
- NLRP14 | c.2985C>A p.Y995* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100205304; called by muse, mutect2, varscan2
- NLRX1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs776155833, COSV52703185; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 40/97 reads (41%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH3 | c.866del p.G289Vfs*83 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as COSV54645852; called by mutect2, pindel, varscan2
- NPY4R | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as rs148351061, COSV65398065; called by muse, mutect2, varscan2
- NQO1 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100276673; called by muse, mutect2, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | catalogued as rs779801455; called by mutect2, varscan2
- NRG3 | c.2066C>T p.T689I (on ENST00000404547 / NM_001370084.1; = p.T665I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100932452, COSV64559422, COSV64586615; called by muse, mutect2, varscan2
- NUP210 | c.4691C>A p.P1564H | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.246); catalogued as COSV99596774; called by muse, mutect2, varscan2
- NUP54 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99345436; called by muse, mutect2, varscan2
- NUTM2G | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100672936; called by muse, varscan2
- OPRK1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs200826073, COSV55570103, COSV55572545; called by muse, mutect2, varscan2
- OR11H12 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV101612452; called by muse, mutect2, varscan2
- OR13C4 | c.867del p.M290Cfs*2 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs765409530; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1C1 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV101376208; called by muse, mutect2, varscan2
- OR2J3 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1330674940, COSV101013653; called by muse, mutect2, varscan2
- OTULINL | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99947301; called by muse, mutect2, varscan2
- PBX2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV100904041; called by muse, mutect2, varscan2
- PCDHA3 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.013); catalogued as rs782500534, COSV100974095; called by muse, mutect2, varscan2
- PCDHA5 | c.859del p.D287Mfs*2 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as COSV65349351; called by mutect2, pindel, varscan2
- PCDHAC1 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99167950; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | catalogued as rs782213177; called by mutect2, pindel, varscan2
- PCDHB16 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as rs1242312573, COSV53370833; called by muse, mutect2, varscan2
- PCDHB3 | c.1947G>C p.E649D | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); catalogued as COSV99166127; called by muse, mutect2, varscan2
- PCDHGA5 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53974328, COSV99543965; called by muse, mutect2, varscan2
- PCNX1 | c.6638C>T p.A2213V | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs770415065, COSV99456731; called by muse, mutect2, varscan2
- PCNX2 | c.3217C>G p.Q1073E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99268962; called by muse, mutect2, varscan2
- PCOLCE | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99775006; called by muse, mutect2, varscan2
- PDE8A | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV100052223; called by muse, mutect2, varscan2
- PDS5A | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216059018, COSV100337510; called by muse, mutect2, varscan2
- PEX5L | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1202434696, COSV55846139, COSV99829535; called by muse, mutect2, varscan2
- PIK3CD | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV100740387; called by muse, mutect2, varscan2
- PLEKHA7 | c.2089A>G p.I697V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100850371; called by muse, mutect2, varscan2
- PLXNA2 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100885699; called by muse, mutect2, varscan2
- PNKP | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV55587629, COSV55588470, COSV99681951; called by muse, mutect2, varscan2
- PNPLA6 | c.2582C>T p.T861M (on ENST00000414982 / NM_001166111.2; = p.T813M on NM_006702.5) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55379490; called by muse, mutect2, varscan2
- POU3F2 | c.876del p.L293Wfs*24 | Frame Shift Del (DEL) | VAF 131/542 reads (24%) | catalogued as COSV60409240; called by mutect2, pindel, varscan2
- PPFIA2 | c.2773G>A p.V925M | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334711, COSV61030597; called by muse, mutect2, varscan2
- PPT2 | c.814dup p.A272Gfs*23 | Frame Shift Ins (INS) | VAF 66/262 reads (25%) | catalogued as rs756707985; called by mutect2, pindel, varscan2
- PRDM1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs1367869245, COSV100958936; called by muse, mutect2, varscan2
- PRDM16 | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV99578197; called by muse, mutect2, varscan2
- PRDM2 | c.4031A>C p.N1344T | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342459; called by muse, mutect2, varscan2
- PRR14 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs760588577, COSV54910769; called by muse, mutect2, varscan2
- PRRT1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52997847; called by muse, mutect2, varscan2
- PSG8 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.304); catalogued as COSV100126520; called by muse, mutect2, varscan2
- PTCHD4 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as COSV100261402; called by muse, mutect2, varscan2
- PVALB | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV99342894; called by muse, mutect2, varscan2
- RALGDS | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100924526; called by muse, mutect2, varscan2
- REG1A | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52069126; called by muse, mutect2, varscan2
- REG3G | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99709623; called by muse, mutect2, varscan2
- RELB | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs754531882, COSV55511236; called by muse, mutect2, varscan2
- RELN | c.3712-1G>C p.X1238_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs1167457394, COSV100634496, COSV59040252; called by muse, mutect2
- RFWD3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.261); catalogued as COSV100736162, COSV100736296; called by muse, mutect2, varscan2
- RHBDD3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1441094645, COSV99328594, COSV99328635; called by muse, mutect2, varscan2
- RNASE9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs766806258, COSV58879970, COSV58880552; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 13/20 reads (65%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF20 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV100874333; called by muse, mutect2
- ROS1 | c.3500del p.L1167* | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs748436511; called by mutect2, pindel, varscan2
- RP1L1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs751227663, COSV66761560; called by muse, mutect2, varscan2
- RPRD2 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs1484668224, COSV100955276; called by muse, mutect2, varscan2
- RTEL1 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.266); catalogued as COSV100542687; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs761969807; called by mutect2, varscan2
- RTTN | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.637); catalogued as rs1440303011, COSV99733458; called by muse, mutect2, varscan2
- RUNX1T1 | c.1135A>T p.R379W (on ENST00000265814 / NM_001198628.1; = p.R352W on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99753961; called by muse, mutect2, varscan2
- SAAL1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100253997; called by muse, mutect2, varscan2
- SAE1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99538124; called by muse, mutect2, varscan2
- SAMD11 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1157613686, COSV58986988; called by muse, mutect2, varscan2
- SCAMP2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99173991; called by muse, mutect2, varscan2
- SCN1A | c.847A>C p.T283P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV100321433; called by muse, mutect2, varscan2
- SEC14L3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs560939192, COSV99306926, COSV99307283; called by muse, mutect2
- SEC23A | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56974470, COSV56979734; called by muse, mutect2, varscan2
- SEC24B | c.1155T>G p.D385E | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV54499883; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SELP | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257933, COSV99740722; called by muse, mutect2, varscan2
- SGSH | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs377605690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGSM1 | c.2980G>T p.D994Y (on ENST00000400359 / NM_001039948.4; = p.D933Y on NM_133454.3) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100771885; called by muse, mutect2, varscan2
- SH3RF1 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52924058, COSV99499361; called by muse, mutect2, varscan2
- SHANK1 | c.6274G>A p.A2092T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs201633631; called by muse, mutect2, varscan2
- SHQ1 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100345219; called by muse, mutect2, varscan2
- SIGLEC9 | c.746C>G p.T249R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99143054; called by muse, mutect2, varscan2
- SLC1A7 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775909830, COSV65194890; called by muse, mutect2, varscan2
- SLC29A4 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1450944894, COSV99786900; called by muse, mutect2, varscan2
- SLC30A4 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV56007108, COSV99970369; called by muse, mutect2, varscan2
- SLC39A12 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101070108; called by muse, mutect2, varscan2
- SLC43A2 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100025151; called by muse, mutect2, varscan2
- SLC4A1AP | c.1694G>A p.R565K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV100389560; called by muse, mutect2, varscan2
- SLCO2A1 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189215; called by muse, mutect2, varscan2
- SNED1 | c.3758G>C p.R1253T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100123204; called by muse, mutect2, varscan2
- SOHLH2 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV101157977; called by muse, mutect2, varscan2
- SPATA19 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54484540; called by muse, mutect2, varscan2
- SPTLC3 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV65463378, COSV65467187; called by muse, mutect2, varscan2
- SSH2 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99282723; called by muse, mutect2, varscan2
- STAT4 | c.2228C>A p.S743Y | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV100636137; called by muse, mutect2
- STK32C | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs370764886; called by muse, mutect2, varscan2
- STK36 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs779201969, COSV55307155; called by muse, mutect2, varscan2
- STRIP1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs762270029, COSV63930752; called by muse, mutect2, varscan2
- SVIL | c.6583G>A p.E2195K (on ENST00000355867 / NM_021738.3; = p.E1769K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100881456; called by muse, mutect2, varscan2
- SVIP | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100829810; called by muse, mutect2, varscan2
- SZT2 | c.5071G>C p.E1691Q (on ENST00000634258 / NM_001365999.1; = p.E1634Q on NM_015284.4) | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as COSV100987569; called by muse, mutect2, varscan2
- TAF1C | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as rs761664370, COSV100499752; called by muse, mutect2, varscan2
- TALDO1 | c.895_897del p.N299del | In Frame Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs756350214; called by mutect2, pindel, varscan2
- TAOK2 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1020575217, COSV99665205; called by muse, mutect2, varscan2
- TDRD3 | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as COSV99540994; called by muse, mutect2, varscan2
- TEP1 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99402998; called by muse, mutect2, varscan2
- TLE4 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99512814; called by muse, mutect2, varscan2
- TMC1 | c.2001C>T p.F667= | Splice Region (SNP) | VAF 54/199 reads (27%) | catalogued as COSV99920195; called by muse, mutect2, varscan2
- TMED5 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100159852; called by muse, mutect2, varscan2
- TMEM104 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100120897; called by muse, mutect2, varscan2
- TMEM132E | c.652G>T p.V218L (on ENST00000321639; = p.V308L on NM_001304438.2) | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100396667; called by muse, mutect2, varscan2
- TMEM74 | c.221G>C p.S74T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99865822; called by muse, mutect2, varscan2
- TNFRSF1B | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs776727613, COSV100884187; called by muse, mutect2, varscan2
- TNRC18 | c.7460C>T p.P2487L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs781681140, COSV100079061; called by muse, mutect2
- TOX | c.1308C>G p.H436Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100789297; called by muse, mutect2, varscan2
- TRIM25 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100381078; called by muse, mutect2, varscan2
- TRIM4 | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV100584373; called by muse, mutect2, varscan2
- TRIM68 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | catalogued as rs749156035, COSV100331647; called by muse, mutect2
- TRMU | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99324670; called by muse, mutect2, varscan2
- TRO | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs368799977, COSV99437023; called by muse, mutect2, varscan2
- TTF2 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs367793200; called by muse, mutect2, varscan2
- TTLL5 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs374016756, COSV100091224; called by muse, mutect2, varscan2
- TTN | c.64819C>T p.H21607Y (on ENST00000591111; = p.H14183Y on NM_003319.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | PolyPhen benign (0.053); catalogued as rs1374089814, COSV100624012; called by muse, mutect2, varscan2
- TTN | c.24116G>T p.R8039L (on ENST00000591111; = p.R7112L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | PolyPhen probably damaging (0.986); catalogued as rs376290076, COSV100624013; called by muse, mutect2, varscan2
- TTN | c.21722G>T p.G7241V (on ENST00000591111; = p.G6314V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/183 reads (31%) | PolyPhen probably damaging (1); catalogued as rs886055294, COSV100624014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP2L | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.968); catalogued as rs753515662, COSV99671970; called by muse, mutect2, varscan2
- UBASH3B | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as rs375615215; called by muse, mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UNC13C | c.2441A>C p.K814T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.388); catalogued as COSV99521537; called by muse, mutect2, varscan2
- UNC45A | c.1577T>C p.L526P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101266018; called by muse, mutect2, varscan2
- UNC5C | c.688del p.R230Dfs*27 | Frame Shift Del (DEL) | VAF 44/209 reads (21%) | catalogued as COSV71661898; called by mutect2, pindel, varscan2
- USP20 | c.988C>A p.R330S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.587); catalogued as COSV100204635; called by muse, mutect2, varscan2
- USP34 | c.2666C>A p.S889* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101277145, COSV68399983; called by muse, mutect2
- VWF | c.6394C>G p.L2132V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99779791; called by muse, mutect2, varscan2
- WDFY3 | c.7418A>G p.E2473G | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV99884973; called by muse, mutect2, varscan2
- WDFY3 | c.6010G>A p.E2004K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV55696337, COSV99884977; called by muse, mutect2, varscan2
- WRN | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99989612; called by muse, mutect2, varscan2
- WSB1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs774835815, COSV52216067; called by muse, mutect2, varscan2
- XIRP2 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.359); catalogued as COSV99738035, COSV99746069; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs745648385; called by mutect2, varscan2
- XPO5 | c.3320G>T p.R1107M | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as COSV99541271; called by muse, mutect2, varscan2
- YTHDC1 | c.2020C>T p.R674W (on ENST00000344157 / NM_001031732.4; = p.R656W on NM_133370.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs756562328, COSV60009675; called by muse, mutect2, varscan2
- ZFHX3 | c.9812C>T p.T3271M | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs759418149, COSV51723989; called by muse, mutect2, varscan2
- ZMIZ2 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99537090; called by muse, mutect2, varscan2
- ZNF236 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV99470964; called by muse, mutect2, varscan2
- ZNF276 | c.251G>A p.G84E (on ENST00000443381 / NM_001113525.2; = p.G9E on NM_152287.4) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99235223; called by muse, mutect2, varscan2
- ZNF423 | c.3392C>T p.P1131L (on ENST00000563137 / NM_001379286.1; = p.P1123L on NM_015069.4) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99283148; called by muse, mutect2, varscan2
- ZNF425 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65200917; called by muse, mutect2, varscan2
- ZNF45 | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99524224; called by muse, mutect2, varscan2
- ZNF608 | c.3215C>A p.P1072H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100102262; called by muse, mutect2, varscan2
- ZNF628 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs1204043019, COSV99220197; called by muse, mutect2, varscan2
- ZNF652 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs746560040, COSV100755648; called by muse, mutect2, varscan2
- ZNF772 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV100582899; called by muse, mutect2, varscan2
- ZNF85 | c.1038dup p.C347Mfs*6 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | catalogued as rs774709579; called by mutect2, pindel, varscan2
- ZNF98 | c.1031A>T p.H344L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100757572; called by mutect2, varscan2
- ZNRF3 | c.778G>C p.E260Q (on ENST00000544604 / NM_001206998.2; = p.E160Q on NM_032173.3) | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as COSV100238815; called by muse, mutect2, varscan2
- ABCE1 | c.938del p.L313Wfs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ACSL3 | c.1529dup p.N510Kfs*9 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- ADRA1B | c.978del p.D327Tfs*88 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 33/138 reads (24%) | called by mutect2, pindel, varscan2
- AOX1 | c.1347dup p.G450Wfs*8 | Frame Shift Ins (INS) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- BCL6 | c.876del p.Y293Tfs*31 | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | called by mutect2, pindel, varscan2
- BRWD1 | c.1058del p.L353Wfs*19 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- C1QL3 | c.137del p.T46Sfs*65 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by pindel, varscan2
- CHAF1A | c.1274del p.K425Rfs*7 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- CLDN15 | c.64del p.V22* | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- CTNNA3 | c.923del p.I308Tfs*40 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- EIF3J | c.715_717del p.D239del | In Frame Del (DEL) | VAF 51/175 reads (29%) | called by pindel, varscan2
- EIF4B | c.9dup p.S4Lfs*7 | Frame Shift Ins (INS) | VAF 105/215 reads (49%) | called by mutect2, pindel, varscan2
- EPHA8 | c.1088dup p.N363Kfs*112 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- FADS2 | c.167del p.G56Afs*31 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- FKBP15 | c.190del p.T64Qfs*6 | Frame Shift Del (DEL) | VAF 110/346 reads (32%) | called by mutect2, varscan2
- FLCN | c.1113dup p.N372Efs*18 | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- FRG2C | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRG1 | c.641del p.N214Mfs*12 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, varscan2
- GAS2L2 | c.1008del p.T337Pfs*25 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- GLB1L | c.1023del p.T342Hfs*29 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- GPR179 | c.4654G>C p.D1552H (on ENST00000621958; = p.D1551H on NM_001004334.4) | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HIVEP3 | c.1601del p.P534Lfs*5 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- HYLS1 | c.833del p.G278Vfs*26 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- KBTBD6 | c.1837del p.C613Afs*34 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- KMT2E | c.4743_4744del p.F1582Yfs*286 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by pindel, varscan2
- KRTAP10-10 | c.267del p.C90Afs*177 | Frame Shift Del (DEL) | VAF 52/174 reads (30%) | called by mutect2, pindel, varscan2
- LPAR2 | c.691del p.R231Afs*36 | Frame Shift Del (DEL) | VAF 50/181 reads (28%) | called by mutect2, pindel, varscan2
- LRP1 | c.12291del p.F4098Lfs*29 | Frame Shift Del (DEL) | VAF 48/93 reads (52%) | called by mutect2, pindel, varscan2
- MRPL21 | c.238del p.V80* | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- MUC13 | c.216del p.I73* | Frame Shift Del (DEL) | VAF 56/277 reads (20%) | called by mutect2, pindel, varscan2
- MYCT1 | c.86del p.F29Sfs*28 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- NLRC4 | c.2793del p.F931Lfs*6 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.4591del p.L1531Cfs*49 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- NPFFR2 | c.1480del p.T494Pfs*15 | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | called by mutect2, pindel, varscan2
- NR2F2 | c.413del p.K138Sfs*7 | Frame Shift Del (DEL) | VAF 39/110 reads (35%) | called by mutect2, pindel, varscan2
- PDGFC | c.533del p.P178Lfs*13 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- PIGW | c.1177dup p.I393Nfs*11 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- PRPF38B | c.182_183del p.M61Nfs*31 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- RASA1 | c.416del p.P139Lfs*35 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- RIPK2 | c.639_640dup p.S214Ifs*26 | Frame Shift Ins (INS) | VAF 23/131 reads (18%) | called by mutect2, varscan2
- RNF213 | c.1032dup p.K345Efs*52 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- SCN5A | c.3024del p.Y1009Tfs*136 (on ENST00000333535 / NM_198056.3; = p.Y1009Tfs*135 on NM_000335.5) | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | called by mutect2, pindel, varscan2
- SLC17A1 | c.1247dup p.L416Ffs*7 | Frame Shift Ins (INS) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- SMG7 | c.2917del p.Q973Rfs*127 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- SRSF8 | c.20del p.P7Lfs*7 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- STYXL2 | c.2454del p.T819Pfs*15 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- SUPT5H | c.1943del p.G648Afs*7 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- TAF7L | c.508del p.T170Pfs*35 | Frame Shift Del (DEL) | VAF 88/163 reads (54%) | called by mutect2, pindel, varscan2
- TRAV10 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TSPAN16 | c.605del p.X202_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- ZNF804B | c.515dup p.N172Kfs*9 | Frame Shift Ins (INS) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- AACS | c.618T>C p.S206= | Silent (SNP) | VAF 175/276 reads (63%) | catalogued as COSV99908222; called by muse, mutect2, varscan2
- ABCC12 | c.2850T>C p.A950= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV100253052; called by muse, mutect2, varscan2
- ACTN2 | c.1236G>A p.T412= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs143566058; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM32 | c.1080C>T p.S360= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs761221427, COSV101165455, COSV65952405; called by muse, mutect2, varscan2
- ADAMTS19 | c.2799C>T p.C933= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs754348548, COSV50735590; called by muse, mutect2, varscan2
- ADAMTSL1 | c.147C>T p.C49= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs895343655, COSV52807809; called by muse, mutect2
- AGO2 | c.2289G>A p.S763= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs746273496, COSV99596199; called by muse, mutect2, varscan2
- AHNAK2 | c.15201C>T p.D5067= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs368198892, COSV100315890; called by muse, mutect2, varscan2
- APH1A | c.42C>T p.F14= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99354480; called by muse, mutect2, varscan2
- ASB6 | c.1089C>T p.F363= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99475816; called by muse, mutect2, varscan2
- ATP2B4 | c.3594A>G p.L1198= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV58185438; called by muse, mutect2, varscan2
- ATXN7L2 | c.1602A>G p.S534= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100149904; called by muse, mutect2, varscan2
- CAMKK2 | c.1314G>A p.P438= | Silent (SNP) | VAF 145/212 reads (68%) | catalogued as rs536615144, COSV61218549; called by muse, mutect2, varscan2
- CASR | c.2823C>T p.C941= (on ENST00000490131; = p.C1018= on NM_000388.4) | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs371038712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEACAM20 | c.969C>A p.A323= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100386981, COSV57601801; called by muse, mutect2, varscan2
- CHD3 | c.5619C>T p.S1873= (on ENST00000330494 / NM_001005273.3; = p.S1839= on NM_005852.4) | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as COSV57874756; called by muse, mutect2, varscan2
- CNBD2 | c.1395C>T p.D465= (on ENST00000373973 / NM_001365709.1; = p.D461= on NM_080834.4) | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs776597449, COSV100839151; called by muse, mutect2, varscan2
- CNIH3 | c.21G>A p.A7= | Silent (SNP) | VAF 150/500 reads (30%) | catalogued as rs770215984, COSV55273300, COSV55279509; called by muse, mutect2, varscan2
- CNOT11 | c.648G>T p.V216= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99179355; called by muse, mutect2, varscan2
- CNOT4 | c.1674C>T p.D558= (on ENST00000541284 / NM_001190850.1; = p.D555= on NM_001190849.2) | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as rs370767888; called by muse, mutect2, varscan2
- CNTNAP2 | c.2235C>T p.C745= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs773833579, COSV62152409; called by muse, mutect2, varscan2
- COL22A1 | c.4329A>C p.P1443= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV100279932; called by muse, mutect2, varscan2
- CPT1B | c.1260C>A p.A420= | Silent (SNP) | VAF 62/201 reads (31%) | catalogued as COSV100376789; called by muse, mutect2, varscan2
- CRTAM | c.519T>C p.D173= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99912202; called by muse, mutect2, varscan2
- CXXC5 | c.552C>T p.S184= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs767217574, COSV100210791; called by muse, mutect2, varscan2
- DAB1 | c.1323G>A p.Q441= (on ENST00000371231; = p.Q408= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs866588545, COSV100976509; called by muse, mutect2, varscan2
- DGCR2 | c.831C>T p.N277= | Silent (SNP) | VAF 142/437 reads (32%) | catalogued as rs755702955, COSV54219684; called by muse, varscan2
- DISP2 | c.3084C>G p.L1028= | Silent (SNP) | VAF 61/174 reads (35%) | catalogued as COSV99140339; called by muse, mutect2, varscan2
- DMRTA1 | c.525C>G p.G175= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100364841; called by muse, mutect2, varscan2
- DNAH3 | c.4434G>A p.A1478= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs546341139, COSV54545708; called by muse, mutect2, varscan2
- DUSP13 | c.45C>A p.A15= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100403701; called by muse, mutect2, varscan2
- EPHA10 | c.1860C>T p.F620= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs1429090981, COSV100361609; called by muse, mutect2, varscan2
- FBXW7 | c.1767C>T p.L589= (on ENST00000281708 / NM_001349798.2; = p.L509= on NM_018315.5) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99659696; called by muse, mutect2, varscan2
- FOXK2 | c.1821C>T p.H607= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs757673228, COSV58876692; called by muse, mutect2, varscan2
- GABRA5 | c.399G>C p.T133= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV100165606; called by muse, mutect2, varscan2
- GABRD | c.378C>T p.I126= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as rs765199464, COSV66080642; called by muse, mutect2, varscan2
- GBA2 | c.2367C>T p.N789= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs143345363; called by muse, mutect2, varscan2
- GLOD4 | c.438T>C p.S146= (on ENST00000301328 / NM_001366247.1; = p.S131= on NM_016080.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100022755; called by muse, mutect2, varscan2
- GON4L | c.1308C>T p.I436= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV55190173; called by muse, mutect2, varscan2
- GON4L | c.684C>T p.L228= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs371195008; called by muse, mutect2, varscan2
- GPRC5C | c.24G>A p.Q8= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100702971; called by muse, mutect2, varscan2
- GRK5 | c.915G>A p.E305= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100963188; called by muse, mutect2, varscan2
- GTF3C4 | c.522C>T p.C174= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as rs372437145; called by muse, mutect2, varscan2
- GTF3C5 | c.225C>T p.C75= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs546891940, COSV59599261; called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- HPX | c.474C>T p.G158= | Silent (SNP) | VAF 79/243 reads (33%) | catalogued as rs575933587, COSV99793463; called by muse, mutect2, varscan2
- HYDIN | c.13758G>A p.E4586= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101125170; called by muse, mutect2, varscan2
- IL4R | c.1614G>A p.E538= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99405282; called by muse, mutect2, varscan2
- ITIH6 | c.2370G>A p.S790= | Silent (SNP) | VAF 49/73 reads (67%) | catalogued as COSV99513773; called by muse, mutect2, varscan2
- ITPRIP | c.1257G>A p.Q419= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs780226438, COSV99532675; called by muse, mutect2, varscan2
- JMJD6 | c.651C>T p.L217= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs1429659753, COSV57974167, COSV57976186; called by muse, mutect2, varscan2
- KCNAB3 | c.273C>A p.S91= | Silent (SNP) | VAF 72/286 reads (25%) | catalogued as COSV100366556; called by muse, mutect2, varscan2
- KIAA0319 | c.2257C>T p.L753= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs748042239, COSV100985737; called by muse, mutect2, varscan2
- KIF1B | c.645C>T p.S215= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99823919; called by muse, mutect2, varscan2
- KRI1 | c.222G>A p.K74= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as rs754594395, COSV57264263; called by muse, mutect2, varscan2
- KRTAP6-2 | c.186T>C p.Y62= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100588940; called by muse, mutect2, varscan2
- LMNTD2 | c.930C>T p.S310= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1385546139, COSV99530652; called by muse, mutect2, varscan2
- MADD | c.4488C>T p.C1496= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100211840; called by mutect2, varscan2
- MARCKS | c.363C>T p.A121= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100893074; called by muse, mutect2, varscan2
- MATN1 | c.567G>A p.R189= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV65651307; called by muse, mutect2, varscan2
- MC2R | c.732C>T p.F244= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100563131, COSV59617991; called by muse, mutect2, varscan2
- MIER2 | c.1395C>T p.D465= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs370482286; called by muse, mutect2, varscan2
- MPO | c.1803C>A p.A601= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as COSV99229202; called by muse, mutect2, varscan2
- MSTN | c.150T>G p.S50= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV99640797; called by muse, mutect2, varscan2
- MTHFD1L | c.1536G>A p.T512= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs186295565, COSV66223750; called by muse, mutect2, varscan2
- MYH6 | c.1917C>T p.G639= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100676876; called by muse, mutect2, varscan2
- MYOF | c.606C>T p.R202= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs776333850, COSV100825158, COSV100826053; called by muse, mutect2, varscan2
- NSUN7 | c.888C>G p.V296= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100349560; called by muse, mutect2
- OCEL1 | c.726G>A p.L242= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV99285800; called by muse, mutect2, varscan2
- OR4A16 | c.438C>A p.A146= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100125358; called by muse, mutect2, varscan2
- OR4A5 | c.852T>C p.Y284= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs780278461, COSV60524930; called by muse, mutect2, varscan2
- OTOF | c.201C>T p.F67= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV99718569; called by muse, mutect2, varscan2
- OXSM | c.336C>T p.I112= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs1374517251, COSV99772092; called by muse, mutect2, varscan2
- PARM1 | c.561T>C p.T187= | Silent (SNP) | VAF 115/301 reads (38%) | catalogued as COSV100268401; called by muse, mutect2, varscan2
- PCNX3 | c.3819C>A p.A1273= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100856566; called by muse, mutect2, varscan2
- PGPEP1L | c.174C>T p.A58= | Silent (SNP) | VAF 67/201 reads (33%) | catalogued as rs764754739, COSV100967407; called by muse, mutect2, varscan2
- PIWIL4 | c.1773C>T p.I591= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs774449382, COSV100133363; called by muse, mutect2, varscan2
- PKD2L2 | c.153C>T p.N51= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99296568; called by muse, mutect2
- PLCB3 | c.1626C>T p.G542= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99657658; called by muse, mutect2, varscan2
- PNPLA7 | c.2826C>T p.G942= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs755001208, COSV99481201; called by muse, mutect2, varscan2
- PRAMEF17 | c.1155C>A p.R385= | Silent (SNP) | VAF 64/247 reads (26%) | catalogued as rs748804075, COSV65816666; called by muse, mutect2, varscan2
- PSMC5 | c.771G>A p.S257= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs758535750, COSV99856243; called by muse, mutect2, varscan2
- PYGM | c.1032C>A p.S344= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV99377475; called by muse, mutect2, varscan2
- RAB40B | c.771G>T p.V257= | Silent (SNP) | VAF 61/231 reads (26%) | catalogued as COSV99483778; called by muse, mutect2, varscan2
- RECQL4 | c.1665G>T p.S555= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs756736123, COSV52880789, COSV99468045; called by muse, mutect2, varscan2
- RNASE12 | c.339C>T p.G113= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs933463221, COSV60087491; called by muse, mutect2, varscan2
- RNF17 | c.4818G>A p.Q1606= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1351993035, COSV99694067; called by muse, mutect2, varscan2
- ROCK2 | c.4077C>T p.A1359= | Silent (SNP) | VAF 66/261 reads (25%) | catalogued as rs1396440480, COSV100255713; called by muse, mutect2, varscan2
- SCN3A | c.1512G>A p.K504= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as COSV51826469; called by muse, mutect2, varscan2
- SCUBE3 | c.226C>A p.R76= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51455183, COSV99235012; called by muse, mutect2, varscan2
- SETD1A | c.3075C>T p.G1025= | Silent (SNP) | VAF 49/191 reads (26%) | catalogued as rs768637479, COSV99353531; called by muse, mutect2, varscan2
- SH2D2A | c.1104C>T p.H368= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1350006818, COSV100949163; called by muse, mutect2, varscan2
- SIX5 | c.726C>T p.L242= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99353572; called by muse, mutect2, varscan2
- SLC12A9 | c.1440C>T p.G480= | Silent (SNP) | VAF 59/184 reads (32%) | catalogued as COSV99308068; called by muse, mutect2, varscan2
- SLC2A9 | c.84G>A p.G28= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs978208661, COSV99305256; called by muse, mutect2, varscan2
- SLC39A12 | c.1152G>T p.G384= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs1204503131, COSV101070109; called by muse, mutect2, varscan2
- SPATA31A3 | c.2238C>T p.I746= | Silent (SNP) | VAF 26/68 reads (38%) | called by mutect2, varscan2
- TAF3 | c.567G>T p.L189= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV100720383; called by muse, mutect2, varscan2
- TFPT | c.468G>A p.A156= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs780452245, COSV57838871; called by muse, mutect2, varscan2
- TGFB1I1 | c.1173G>A p.P391= (on ENST00000394863 / NM_001042454.3; = p.P374= on NM_015927.4) | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs149594870; called by muse, mutect2, varscan2
- THSD1 | c.1003C>T p.L335= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99319015; called by muse, mutect2, varscan2
- THSD7A | c.888C>T p.A296= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as COSV101448837; called by muse, mutect2, varscan2
- TMEM126A | c.249C>T p.Y83= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100449545; called by muse, mutect2, varscan2
- TMPRSS15 | c.2415C>T p.G805= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs771901034, COSV53036046; called by muse, mutect2, varscan2
- TOP2A | c.624C>A p.P208= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101396334; called by muse, mutect2, varscan2
- TRAP1 | c.276C>T p.A92= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs370347742; called by muse, mutect2, varscan2
- TRAPPC11 | c.621G>A p.V207= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100591988; called by muse, mutect2, varscan2
- TRIM5 | c.756C>T p.G252= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs768710240, COSV59901222; called by muse, mutect2, varscan2
- TRRAP | c.11148C>T p.D3716= (on ENST00000359863 / NM_001244580.1; = p.D3687= on NM_003496.3) | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs772027669, COSV100705476; called by muse, mutect2, varscan2
- TTLL10 | c.1074G>A p.A358= (on ENST00000379289 / NM_001130045.2; = p.A285= on NM_153254.3) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs753887558, COSV101016835; called by muse, mutect2, varscan2
- TTN | c.87570A>C p.T29190= (on ENST00000591111; = p.T21766= on NM_003319.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100624005; called by muse, mutect2, varscan2
- UBR2 | c.408T>C p.H136= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100868660; called by muse, mutect2, varscan2
- UFL1 | c.1657T>C p.L553= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100990122; called by muse, mutect2, varscan2
- VN1R5 | c.756C>A p.A252= | Silent (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- VPS13D | c.5136A>G p.S1712= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV99167882; called by muse, mutect2, varscan2
- VWA3B | c.423C>T p.C141= | Silent (SNP) | VAF 84/283 reads (30%) | catalogued as rs375112578; called by muse, mutect2, varscan2
- XIRP1 | c.3624G>A p.G1208= | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as COSV100453846; called by muse, mutect2, varscan2
- ZBTB18 | c.1239G>A p.S413= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs147690899, COSV62396201; called by muse, mutect2, varscan2
- ZNF292 | c.6180T>C p.I2060= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100370898; called by muse, varscan2
- ZNF804A | c.348C>A p.R116= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV56463180; called by muse, mutect2, varscan2
- ACP4 | chr19:50798450 C>T | 3'Flank (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99567827; called by muse, mutect2, varscan2
- ACSL5 | c.-142C>T | 5'UTR (SNP) | VAF 51/184 reads (28%) | catalogued as COSV100634723, COSV61129205; called by muse, mutect2, varscan2
- ANKRD13D | c.*1515C>T | 3'UTR (SNP) | VAF 31/100 reads (31%) | catalogued as COSV100354737; called by muse, mutect2, varscan2
- C9orf163 | n.1193G>A | RNA (SNP) | VAF 18/52 reads (35%) | catalogued as rs759287711; called by muse, mutect2, varscan2
- CACNA1C | c.1481+565G>C | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as rs372658528, COSV100221217; called by muse, mutect2, varscan2
- COLCA2 | chr11:111296177 C>T | 5'Flank (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- DCAF13 | c.-18G>A | 5'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99884616; called by muse, mutect2, varscan2
- DNM1P46 | n.537G>C | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- DOK3 | c.-141G>A | 5'UTR (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100394475; called by muse, mutect2, varscan2
- GRM7 | c.2698+6126A>C | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as rs754728660, COSV100735519; called by muse, mutect2, varscan2
- HERC2P3 | n.880C>A | RNA (SNP) | VAF 52/239 reads (22%) | called by muse, mutect2, varscan2
- HERC2P3 | n.765G>A | RNA (SNP) | VAF 40/221 reads (18%) | catalogued as rs1364798920; called by muse, mutect2, varscan2
- HERC2P3 | n.764G>A | RNA (SNP) | VAF 38/219 reads (17%) | called by muse, mutect2, varscan2
- LIMK2 | c.1773-1244C>T | Intron (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99314187; called by muse, mutect2, varscan2
- MAGED1 | c.45+311del | Intron (DEL) | VAF 17/26 reads (65%) | called by mutect2, varscan2
- RAC1 | c.226-1427dup | Intron (INS) | VAF 7/34 reads (21%) | called by pindel, varscan2
- RUNX1T1 | c.88+13416C>T | Intron (SNP) | VAF 77/266 reads (29%) | catalogued as COSV99753965; called by muse, mutect2, varscan2
- SNORD115-39 | n.79G>A | RNA (SNP) | VAF 115/387 reads (30%) | called by muse, mutect2, varscan2
- SNORD115-44 | n.59C>T | RNA (SNP) | VAF 140/508 reads (28%) | catalogued as rs754626435; called by muse, mutect2, varscan2
- TRPA1 | c.-2C>T | 5'UTR (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100084873; called by muse, mutect2, varscan2
